Somatic mutation profile of tumor specimen C3L-02116-03 (aliquot CPT0109200010_1) from CPTAC case C3L-02116, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.6 years (24,692 days).
Specimen C3L-02116-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16b8c789-99e8-4711-bf69-1e5042f8a296.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02116-31 (Blood Derived Normal), aliquot CPT0109240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf6a54ec-9935-481c-9d60-c6603885963b

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Intron 3, Splice Site 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 44/356 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DRGX | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65136841; called by muse, mutect2
- EEF1A1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.44); catalogued as COSV58549690, COSV58550143; called by muse, mutect2
- NXPE1 | c.1126C>T p.L376F (on ENST00000424269; = p.L234F on NM_152315.5) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as rs1289996095; called by muse, varscan2
- OR10J5 | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 53/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58386920; called by muse, mutect2, varscan2
- PDZD2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 86/845 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753717715, COSV56875257; called by mutect2, varscan2
- SLC22A24 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371518525, COSV70301809; called by muse, mutect2
- SLC44A4 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 17/584 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0.098); catalogued as rs1264379730, COSV57668452; called by muse, mutect2
- SMAD4 | c.1308+1G>C p.X436_splice | Splice Site (SNP) | VAF 50/365 reads (14%) | catalogued as COSV61685036, COSV61690413; called by muse, mutect2, varscan2
- THBS1 | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1280302983; called by muse, mutect2
- WNT5B | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1262622082, COSV100148689; called by muse, mutect2
- XIRP2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 39/698 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.286); catalogued as COSV54687771, COSV99743517; called by muse, mutect2
- ACSM4 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD31 | c.3250del p.V1084Lfs*6 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GAS2L3 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 58/701 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2
- H2AW | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 66/819 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HLA-DQB2 | c.782G>T p.G261V (on ENST00000435145; = p.X224_splice on NM_001198858.2) | Missense Mutation (SNP) | VAF 21/418 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- LRP2 | c.3431-1G>A p.X1144_splice | Splice Site (SNP) | VAF 34/448 reads (8%) | called by muse, mutect2
- MDGA2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 34/882 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- NAIP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TAP2 | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 64/1428 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2
- TBC1D9B | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR72 | c.2811G>T p.K937N | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADSS1 | c.1086G>A p.T362= | Silent (SNP) | VAF 37/334 reads (11%) | catalogued as rs760343931, COSV100272324, COSV58272681; called by muse, mutect2, varscan2
- CACNA1B | c.6699C>T p.S2233= | Silent (SNP) | VAF 48/350 reads (14%) | catalogued as rs200996202, COSV53136715; called by muse, mutect2, varscan2
- DUSP26 | c.342G>A p.L114= | Silent (SNP) | VAF 103/921 reads (11%) | catalogued as rs1280521853, COSV99823597; called by muse, mutect2, varscan2
- FAH | c.441G>T p.A147= | Silent (SNP) | VAF 54/920 reads (6%) | catalogued as rs141863249, CD119463; called by muse, mutect2
- HYDIN | c.3024C>T p.G1008= | Silent (SNP) | VAF 89/1066 reads (8%) | called by muse, mutect2
- IGF1R | c.3225A>G p.T1075= | Silent (SNP) | VAF 62/1302 reads (5%) | called by muse, mutect2
- PCDHGA9 | c.399C>T p.F133= | Silent (SNP) | VAF 58/543 reads (11%) | called by muse, mutect2, varscan2
- PPP1R15A | c.1956T>A p.A652= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- SCN5A | c.1365C>T p.T455= | Silent (SNP) | VAF 46/330 reads (14%) | catalogued as rs747138429; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC31B | c.318G>A p.L106= | Silent (SNP) | VAF 21/416 reads (5%) | called by muse, mutect2
- TGM7 | c.270C>T p.S90= | Silent (SNP) | VAF 54/808 reads (7%) | catalogued as rs753185732, COSV101476840; called by muse, mutect2
- C3P1 | n.2561C>T | RNA (SNP) | VAF 22/348 reads (6%) | catalogued as rs771970106; called by muse, mutect2
- CCDC158 | c.1029+3589A>G | Intron (SNP) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- CFAP20DC | c.550+9A>C | Intron (SNP) | VAF 44/493 reads (9%) | called by muse, mutect2
- FICD | c.302-142C>T | Intron (SNP) | VAF 81/999 reads (8%) | catalogued as rs774851840; called by muse, mutect2
- MIR522 | n.30G>A | RNA (SNP) | VAF 14/243 reads (6%) | catalogued as rs146976572; called by muse, mutect2
